Gene-level copy-number profile of tumor specimen ALCH-B2M3-TTP1-A from ALCHEMIST case ALCH-B2M3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 74.5 years (27,220 days).
Specimen ALCH-B2M3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 940157f8-0d8a-4b74-97b8-8194f4ed2908.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2M3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/cc56a995-5bf9-41ca-b452-30ab659306e1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 214; copy number 2: 10,222; copy number 3: 15,865; copy number 4: 26,379; copy number 5: 2,870; copy number 6: 2,824; copy number 7: 105; copy number 8: 104; copy number 9: 5; copy number 10: 284; copy number 11: 3; copy number 12: 2; copy number 15: 11; copy number 22: 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:150,846,523–150,904,983, 2 genes: IRGM, ZNF300.
- chr6:108,551,018–108,684,774, 3 genes: AL391646.1, FOXO3, SUMO2P8.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 305 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:391,752–5,089,487, 104 genes, copy number 10 (broad region; genes not listed).
- chr6:5,261,044–5,829,192, 1 gene, copy number 10 (within-gene range 2–10): FARS2.
- chr6:5,609,227–18,155,077, 192 genes, copy number 10–15 (broad region; genes not listed).
- chr6:60,789,805–60,942,327, 3 genes, copy number 9: AL512427.2, AL512427.1, RBBP4P3.
- chr21:43,115,334–43,115,709, 1 gene, copy number 11: MRPL51P2.
- chr22:18,636,445–18,757,906, 4 genes, copy number 9–22: CA15P2, PPP1R26P2, PPP1R26P4, FAM230E.

Autosomal genes at a single copy (total copy number 1): 206. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
